Somatic mutation profile of tumor specimen 0DWI1C from CCDI case PBCPAG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 3.2 years (1,181 days).
Specimen 0DWI1C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7eb4552-1424-4246-b7c9-6376ce88ae62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWHZ9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc29524f-e484-4652-ad68-29d63e3364a2

The open-access MAF lists 38 somatic variants for this specimen: 20 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Intron 4, 3'UTR 4, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 345/699 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- ABHD8 | c.1149G>A p.E383= | Splice Region (SNP) | VAF 63/361 reads (17%) | catalogued as COSV99917069; called by muse, mutect2, varscan2
- MSLN | c.1273C>T p.R425C (on ENST00000382862 / NM_013404.4; = p.R417C on NM_005823.6) | Missense Mutation (SNP) | VAF 27/442 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs186022569, COSV99558778; called by muse, mutect2
- PEX7 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 212/758 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs1388999826; called by muse, mutect2, varscan2
- REC114 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1172575671, COSV58521574; called by muse, mutect2, varscan2
- RELA | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 169/843 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs774014347; called by muse, mutect2, varscan2
- SLC15A2 | c.401C>G p.P134R | Missense Mutation (SNP) | VAF 108/659 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.695); catalogued as COSV99815489; called by muse, mutect2, varscan2
- BCAP31 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 182/919 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CD200 | c.341C>T p.A114V (on ENST00000473539 / NM_001004196.3; = p.A89V on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/1190 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.138); called by muse, mutect2
- DCAF11 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 40/742 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2
- FAM170A | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 80/935 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2
- H4C12 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- HADHB | c.1104G>T p.L368F | Missense Mutation (SNP) | VAF 222/900 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- HDAC8 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 203/946 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- MAST4 | c.4339G>A p.E1447K (on ENST00000403625 / NM_001164664.2; = p.E1258K on NM_015183.3) | Missense Mutation (SNP) | VAF 96/568 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSMO1 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 257/1070 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MST1 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 17/848 reads (2%) | SIFT tolerated (0.17); PolyPhen benign (0.088); called by muse, mutect2
- PALB2 | c.2562C>A p.N854K | Missense Mutation (SNP) | VAF 190/788 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by mutect2, varscan2
- SPAG9 | c.498_500dup p.M166dup | In Frame Ins (INS) | VAF 78/542 reads (14%) | called by mutect2, varscan2
- STARD8 | c.1985C>A p.T662N | Missense Mutation (SNP) | VAF 102/574 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by mutect2, varscan2
- BSN | c.5652G>A p.A1884= | Silent (SNP) | VAF 99/506 reads (20%) | catalogued as rs760305287, COSV99609084; called by muse, mutect2, varscan2
- CD248 | c.486C>T p.G162= | Silent (SNP) | VAF 98/500 reads (20%) | catalogued as rs755764575; called by muse, varscan2
- FIZ1 | c.849C>T p.G283= | Silent (SNP) | VAF 37/155 reads (24%) | catalogued as rs1232507091; called by muse, mutect2, varscan2
- HSD17B10 | c.354T>C p.L118= | Silent (SNP) | VAF 120/626 reads (19%) | called by muse, mutect2, varscan2
- PCDHB6 | c.657G>T p.P219= | Silent (SNP) | VAF 239/475 reads (50%) | catalogued as COSV50715019, COSV50741249; called by muse, mutect2, varscan2
- PLCB1 | c.1632G>T p.V544= | Silent (SNP) | VAF 230/1040 reads (22%) | called by muse, mutect2, varscan2
- STARD8 | c.2754C>A p.P918= | Silent (SNP) | VAF 113/648 reads (17%) | called by muse, mutect2, varscan2
- TMEM262 | c.327C>T p.I109= (on ENST00000530719 / NM_001282448.1; = p.R97* on NM_001242631.2) | Silent (SNP) | VAF 166/842 reads (20%) | catalogued as rs1007607650; called by muse, mutect2, varscan2
- TRIM77 | c.1020A>G p.K340= | Silent (SNP) | VAF 78/1884 reads (4%) | called by muse, mutect2
- ZNF792 | c.54C>T p.D18= | Silent (SNP) | VAF 44/237 reads (19%) | catalogued as rs373145674; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1163+24C>T | Intron (SNP) | VAF 56/205 reads (27%) | catalogued as rs374666080; called by muse, mutect2, varscan2
- HSF2 | c.*72G>A | 3'UTR (SNP) | VAF 25/84 reads (30%) | called by mutect2, varscan2
- MPP1 | c.*6T>C | 3'UTR (SNP) | VAF 101/565 reads (18%) | called by muse, mutect2, varscan2
- NDUFA1 | c.*54C>T | 3'UTR (SNP) | VAF 120/741 reads (16%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1371+4437G>T | Intron (SNP) | VAF 137/505 reads (27%) | called by muse, mutect2, varscan2
- SETD6 | c.*4529A>C | 3'UTR (SNP) | VAF 42/125 reads (34%) | called by muse, mutect2, varscan2
- STAB1 | c.4762-11C>T | Intron (SNP) | VAF 82/420 reads (20%) | catalogued as rs753111530; called by muse, mutect2, varscan2
- TNFRSF14 | c.552-79G>T | Intron (SNP) | VAF 50/134 reads (37%) | called by muse, mutect2, varscan2
